Somatic mutation profile of tumor specimen ALCH-B251-TTP1-A (aliquot ALCH-B251-TTP1-A-1-0-D-A76N-36) from ALCHEMIST case ALCH-B251, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,873 days).
Specimen ALCH-B251-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6565e88-51b8-4d2e-a721-fc32fe4a1297.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B251-NB1-A (Blood Derived Normal), aliquot ALCH-B251-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78dadab6-66c3-415c-bf4f-624c8f01d478

The open-access MAF lists 289 somatic variants for this specimen: 202 protein-altering or splice-affecting, 53 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 53, Nonsense Mutation 19, Intron 15, RNA 8, Splice Site 5, 3'UTR 4, 5'UTR 4, Frame Shift Del 2, Splice Region 2, 3'Flank 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 210/868 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 48/330 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA2 | c.7391C>T p.T2464M (on ENST00000614293; = p.T2434M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs1173334061, COSV55799624; called by muse, mutect2
- ABL1 | c.2921C>T p.T974I | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.131); catalogued as rs754384449; called by muse, mutect2, varscan2
- ACOX2 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1457822941; called by muse, mutect2
- ADGRG4 | c.5656C>A p.P1886T | Missense Mutation (SNP) | VAF 18/193 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs757139127; called by muse, mutect2, varscan2
- ALYREF | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as rs1381337363, COSV58669133; called by muse, mutect2
- ANKRD11 | c.1459G>T p.E487* | Nonsense Mutation (SNP) | VAF 30/235 reads (13%) | catalogued as COSV99967916; called by muse, mutect2, varscan2
- ANKRD36C | c.1819G>T p.G607* | Nonsense Mutation (SNP) | VAF 25/332 reads (8%) | catalogued as rs1410751482; called by muse, mutect2
- BCAT2 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 12/91 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760322244; called by muse, mutect2, varscan2
- BRDT | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1390595393, COSV62864718; called by muse, mutect2
- C12orf50 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.027); catalogued as rs375468699; called by muse, mutect2, varscan2
- CAPN12 | c.443G>C p.R148P | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV61018460; called by muse, mutect2
- CDH4 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as rs555725508, COSV64669075; called by muse, mutect2, varscan2
- CELF2 | c.733G>T p.G245* (on ENST00000416382 / NM_001025077.3; = p.G252* on NM_006561.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV59976428; called by muse, mutect2
- CLDN23 | c.326C>G p.P109R | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs972469268; called by muse, mutect2, varscan2
- COL21A1 | c.2072C>A p.P691H | Missense Mutation (SNP) | VAF 27/305 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759722305; called by muse, mutect2
- COL25A1 | c.781-1G>T p.X261_splice | Splice Site (SNP) | VAF 26/295 reads (9%) | catalogued as COSV67652346; called by muse, mutect2
- COL4A1 | c.3070G>T p.E1024* | Nonsense Mutation (SNP) | VAF 50/457 reads (11%) | catalogued as COSV101010975; called by muse, mutect2, varscan2
- COPG1 | c.1421G>C p.R474P | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59116698; called by muse, mutect2, varscan2
- CRB1 | c.2533G>C p.G845R | Missense Mutation (SNP) | VAF 27/383 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV66331697; called by muse, mutect2
- CSMD3 | c.8098T>C p.F2700L | Missense Mutation (SNP) | VAF 82/388 reads (21%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.994); catalogued as rs1279730037; called by muse, varscan2
- ETF1 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as rs1377091270; called by muse, mutect2
- FAT4 | c.10253G>T p.G3418V | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100630558, COSV100630656; called by muse, mutect2
- FCHO2 | c.1141A>G p.I381V | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs763411156; called by muse, mutect2
- GABRB3 | c.1078C>A p.R360= | Splice Region (SNP) | VAF 32/350 reads (9%) | catalogued as COSV100159362, COSV100160423; called by muse, mutect2
- GPKOW | c.176G>C p.S59T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV50242445; called by muse, mutect2, varscan2
- GRIN3A | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100701788, COSV62458149; called by muse, mutect2
- GUCY2F | c.2117C>T p.S706F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV99485902; called by muse, mutect2
- HBE1 | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 21/190 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.418); catalogued as COSV53080831; called by muse, mutect2, varscan2
- IGHD5-24 | c.18T>G p.I6M | Missense Mutation (SNP) | VAF 7/65 reads (11%) | catalogued as rs559651952; called by muse, mutect2, varscan2
- KCNJ13 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99289253; called by muse, mutect2
- KLHL34 | c.704G>T p.R235L | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.488); catalogued as COSV65280264; called by muse, mutect2
- LAMA2 | c.5117G>A p.R1706Q | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs777116636; called by muse, mutect2, varscan2
- LAMA3 | c.8452G>T p.V2818F (on ENST00000313654 / NM_198129.4; = p.V1209F on NM_000227.6) | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99336098; called by muse, mutect2, varscan2
- LILRB5 | c.4A>G p.T2A | Missense Mutation (SNP) | VAF 5/145 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV60258143; called by muse, mutect2
- MASP1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV51459001, COSV51460493; called by muse, mutect2
- MMP2 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 19/120 reads (16%) | catalogued as COSV99527537, COSV99527977; called by muse, mutect2, varscan2
- MS4A3 | c.187C>A p.L63M | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53937126; called by muse, mutect2
- NAP1L5 | c.416A>G p.E139G | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99986191; called by muse, mutect2
- NPC2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 28/255 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs483352893, CM146781; called by muse, mutect2, varscan2
- NTRK3 | c.1834C>G p.P612A | Missense Mutation (SNP) | VAF 21/324 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV62315183; called by muse, mutect2
- OR4K15 | c.403G>A p.E135K (on ENST00000305051; = p.E111K on NM_001005486.1) | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV59301656; called by muse, mutect2
- OR51L1 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.114); catalogued as COSV100386439, COSV58625470; called by muse, mutect2
- PCDH15 | c.4958C>A p.T1653K | Missense Mutation (SNP) | VAF 43/327 reads (13%) | SIFT deleterious, low confidence (0.02); catalogued as COSV64670190; called by muse, mutect2, varscan2
- PCDH19 | c.3131G>A p.C1044Y (on ENST00000373034 / NM_001184880.2; = p.C996Y on NM_020766.3) | Missense Mutation (SNP) | VAF 23/232 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.365); catalogued as COSV55268343, COSV55268629; called by muse, mutect2
- PCDHB11 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 46/300 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.045); catalogued as rs782776198, COSV61314859; called by muse, mutect2, varscan2
- PIGA | c.1083G>T p.K361N | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV100363499; called by muse, varscan2
- POLR3GL | c.19G>A p.G7S | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs782404386, COSV100996741; called by muse, mutect2, varscan2
- RPTN | c.363C>A p.H121Q | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as COSV60166463; called by muse, mutect2
- SCN5A | c.5329G>C p.V1777L (on ENST00000333535 / NM_198056.3; = p.V1776L on NM_000335.5) | Missense Mutation (SNP) | VAF 32/300 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as CM012465, COSV61114979, COSV61119788; called by muse, mutect2, varscan2
- SEC23IP | c.1313-5G>T | Splice Region (SNP) | VAF 29/218 reads (13%) | catalogued as COSV64832909; called by muse, mutect2, varscan2
- SF3B1 | c.2131G>C p.A711P | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs866566860; called by muse, mutect2
- SI | c.3257G>T p.W1086L | Missense Mutation (SNP) | VAF 25/386 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.943); catalogued as COSV100016715, COSV52264380; called by muse, mutect2
- SLC30A8 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 96/391 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.757); catalogued as rs772589300, COSV69967924; called by muse, mutect2, varscan2
- SORCS3 | c.3484G>T p.D1162Y | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100864998; called by muse, mutect2, varscan2
- SUSD1 | c.1915G>T p.A639S | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.07); catalogued as rs377416608; called by muse, mutect2
- TMEM125 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs533398952, COSV71326992; called by muse, mutect2, varscan2
- UCP1 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53767893; called by muse, mutect2, varscan2
- WNT3 | c.169C>G p.R57G | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56646192; called by muse, mutect2, varscan2
- ZFHX4 | c.10066C>A p.Q3356K | Missense Mutation (SNP) | VAF 70/349 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.043); catalogued as COSV50644368; called by muse, mutect2, varscan2
- ZNF285 | c.510C>G p.Y170* | Nonsense Mutation (SNP) | VAF 11/175 reads (6%) | catalogued as COSV58410252; called by muse, mutect2
- ZNF597 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV57084042; called by muse, mutect2, varscan2
- ABCA13 | c.4223C>G p.S1408C | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABI3 | c.766C>G p.P256A | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACTN2 | c.814G>T p.V272F | Missense Mutation (SNP) | VAF 78/397 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ADAM30 | c.1172A>T p.N391I | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2
- ADAMTS20 | c.2230G>T p.A744S | Missense Mutation (SNP) | VAF 23/170 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRL3 | c.212G>T p.R71I | Missense Mutation (SNP) | VAF 21/237 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.114); called by muse, mutect2
- AFF2 | c.609G>T p.Q203H | Missense Mutation (SNP) | VAF 27/330 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.65); called by muse, mutect2
- ANKRD11 | c.3771A>T p.K1257N | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- ANO3 | c.1028A>G p.H343R | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AQR | c.4212G>T p.L1404F | Missense Mutation (SNP) | VAF 15/156 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2
- ARHGEF33 | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- ASCC3 | c.1507G>T p.A503S | Missense Mutation (SNP) | VAF 50/673 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BPIFC | c.939T>A p.F313L | Missense Mutation (SNP) | VAF 21/300 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2
- BRCA1 | c.4264G>T p.G1422W | Missense Mutation (SNP) | VAF 16/183 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- BRCA1 | c.4263T>A p.H1421Q | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- C5orf22 | c.873A>T p.E291D | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CCDC180 | c.4861G>T p.E1621* | Nonsense Mutation (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- CD70 | c.370C>A p.H124N | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2
- CDH13 | c.193_200del p.R65Gfs*59 | Frame Shift Del (DEL) | VAF 12/128 reads (9%) | called by mutect2, pindel
- CFAP54 | c.1947G>T p.Q649H | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2
- CFAP92 | c.2398G>T p.A800S | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.026); called by muse, mutect2
- CHD6 | c.3878G>A p.G1293D | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRNA4 | c.1108C>G p.R370G | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CLCA2 | c.1529T>C p.L510S | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- CNTNAP2 | c.1348G>T p.G450C | Missense Mutation (SNP) | VAF 37/281 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- COL12A1 | c.2612A>T p.Q871L | Missense Mutation (SNP) | VAF 45/445 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- COL22A1 | c.940del p.Q314Rfs*30 | Frame Shift Del (DEL) | VAF 30/190 reads (16%) | called by mutect2, pindel, varscan2
- CRACD | c.1924C>A p.P642T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CREBBP | c.2353G>T p.A785S | Missense Mutation (SNP) | VAF 37/398 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.038); called by muse, mutect2
- CSPP1 | c.886C>T p.H296Y (on ENST00000676605; = p.H255Y on NM_024790.6) | Missense Mutation (SNP) | VAF 20/438 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.056); called by muse, mutect2
- CTNNA2 | c.2396T>C p.V799A | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- DENND2A | c.2885G>T p.R962L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- DNAH1 | c.4423G>T p.A1475S | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.48); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- DNAH12 | c.1514G>T p.C505F | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, varscan2
- DNAH9 | c.12778G>T p.G4260C | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- DNAJC21 | c.98A>G p.D33G | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- DOCK11 | c.677G>T p.C226F | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DOK2 | c.554C>A p.P185H | Missense Mutation (SNP) | VAF 46/209 reads (22%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- DSN1 | c.356-1G>A p.X119_splice | Splice Site (SNP) | VAF 59/387 reads (15%) | called by muse, mutect2, varscan2
- DUSP9 | c.239T>A p.L80Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EFNB3 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- EGFLAM | c.1243T>A p.F415I | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EHBP1 | c.2002G>T p.D668Y | Missense Mutation (SNP) | VAF 25/292 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- EIF4G1 | c.2252A>T p.D751V (on ENST00000346169 / NM_198241.3; = p.D556V on NM_004953.5) | Missense Mutation (SNP) | VAF 25/248 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- EML6 | c.617C>T p.A206V | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ESPNL | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- F8 | c.3932C>A p.A1311E | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- FAM13A | c.2154A>T p.Q718H | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- FNDC1 | c.2615G>C p.S872T | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GLI2 | c.3782G>T p.G1261V (on ENST00000361492 / NM_001374353.1; = p.G1278V on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1030C>G p.R344G | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- GPA33 | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.001); called by muse, mutect2
- GPR4 | c.355G>A p.V119M | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, varscan2
- GPRC6A | c.2678A>C p.Q893P | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- GRIK5 | c.889T>G p.Y297D | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); called by muse, mutect2
- HJV | c.1238C>A p.P413Q (on ENST00000336751 / NM_213653.4; = p.P300Q on NM_145277.5) | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HUWE1 | c.7437G>T p.L2479F | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.001); called by muse, mutect2
- ICE1 | c.2852G>T p.C951F | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- IGF2R | c.2389A>T p.M797L | Missense Mutation (SNP) | VAF 46/557 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2
- IGHE | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IL17F | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 11/141 reads (8%) | called by muse, mutect2
- IMPG1 | c.1037C>A p.P346Q | Missense Mutation (SNP) | VAF 23/417 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.031); called by muse, mutect2
- KCNIP1 | c.295A>T p.S99C (on ENST00000411494 / NM_001034837.3; = p.S88C on NM_014592.4) | Missense Mutation (SNP) | VAF 29/300 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.135); called by muse, mutect2
- KCNK13 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA2 | c.5243A>T p.E1748V | Missense Mutation (SNP) | VAF 19/174 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- LAMA5 | c.10158G>T p.R3386S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- LILRA5 | c.529G>T p.G177* | Nonsense Mutation (SNP) | VAF 17/168 reads (10%) | called by muse, mutect2, varscan2
- MAGEB6B | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 17/287 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- MAP3K15 | c.3201G>T p.M1067I | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MAT1A | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 9/295 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MBNL3 | c.651G>T p.M217I | Missense Mutation (SNP) | VAF 10/256 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- METTL22 | c.463G>T p.D155Y | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.85); called by muse, mutect2
- MYCBP2 | c.13156G>C p.A4386P (on ENST00000357337; = p.A4424P on NM_015057.5) | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MYH3 | c.3191A>C p.Q1064P | Missense Mutation (SNP) | VAF 47/475 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- NINL | c.2494G>T p.D832Y | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- NLRC4 | c.1063C>A p.H355N | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2
- NPAS4 | c.1361C>A p.T454N | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR10G9 | c.611T>A p.L204Q | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- OR1L4 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 9/150 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR2J1 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T6 | c.704A>T p.K235M | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OR7G2 | c.799T>C p.S267P | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PANX2 | c.1382A>T p.K461M | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PCDH1 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- PCSK1N | c.697G>T p.E233* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2
- PDGFRA | c.2755G>T p.D919Y | Missense Mutation (SNP) | VAF 54/437 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- PEX5 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 11/353 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- PI15 | c.553G>T p.G185* | Nonsense Mutation (SNP) | VAF 12/251 reads (5%) | called by muse, mutect2
- PIK3CB | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- PLPPR4 | c.1731G>T p.M577I | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- PLXNA3 | c.3595G>T p.G1199C | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- POMGNT2 | c.191G>T p.G64V | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPP4R3C | c.2135G>T p.G712V | Missense Mutation (SNP) | VAF 35/370 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PRDM9 | c.589C>A p.P197T | Missense Mutation (SNP) | VAF 92/491 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRSS55 | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 35/210 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRUNE2 | c.1852G>T p.E618* | Nonsense Mutation (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- RALYL | c.729A>T p.Q243H | Missense Mutation (SNP) | VAF 33/138 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAPGEF3 | c.1921C>G p.L641V (on ENST00000389212; = p.L599V on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by mutect2, varscan2
- RASGEF1C | c.1316C>A p.A439D | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); called by muse, mutect2
- RBBP7 | c.1118C>A p.T373N | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- REG1A | c.70G>T p.E24* | Nonsense Mutation (SNP) | VAF 28/241 reads (12%) | called by muse, mutect2, varscan2
- RGMA | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ROBO2 | c.3300C>A p.D1100E | Missense Mutation (SNP) | VAF 25/331 reads (8%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2
- ROM1 | c.664C>A p.P222T | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RTL5 | c.653C>A p.P218Q | Missense Mutation (SNP) | VAF 23/182 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- RYR2 | c.12730G>T p.A4244S | Missense Mutation (SNP) | VAF 81/390 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RYR3 | c.7780G>A p.D2594N (on ENST00000389232; = p.D2595N on NM_001036.6) | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.225); called by muse, mutect2
- SAMD4B | c.677G>A p.C226Y | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- SATL1 | c.991C>A p.Q331K (on ENST00000395409; = p.Q518K on NM_001012980.2) | Missense Mutation (SNP) | VAF 33/233 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- SEC16B | c.3148C>A p.L1050I | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SHC2 | c.611A>G p.K204R | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- SHOC1 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A9 | c.1694A>T p.K565M | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- SLC5A2 | c.56T>A p.L19Q | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SLC8A1 | c.2038+1G>T p.X680_splice | Splice Site (SNP) | VAF 18/155 reads (12%) | called by muse, mutect2, varscan2
- SLC9A9 | c.457A>T p.R153* | Nonsense Mutation (SNP) | VAF 19/270 reads (7%) | called by muse, mutect2
- SMOC1 | c.198G>T p.M66I | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SRMS | c.787+2T>A p.X263_splice | Splice Site (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2, varscan2
- SRPX2 | c.923C>A p.S308Y | Missense Mutation (SNP) | VAF 28/337 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.395); called by muse, mutect2
- SSBP3 | c.286G>T p.A96S | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.158); called by muse, mutect2
- STS | c.520A>T p.T174S | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2
- SUPT20H | c.1212-2A>T p.X404_splice (on ENST00000350612 / NM_001014286.3; = p.X405_splice on NM_017569.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- TBC1D8B | c.2857A>G p.S953G | Missense Mutation (SNP) | VAF 26/310 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.109); called by muse, mutect2
- TDGF1 | c.525T>G p.F175L | Missense Mutation (SNP) | VAF 28/350 reads (8%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- THOC2 | c.2525A>G p.Q842R | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- TIMM17B | c.323G>A p.G108D | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TM4SF18 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 17/187 reads (9%) | called by muse, mutect2, varscan2
- TRPC5 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 17/294 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- TTC33 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 61/270 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.376); called by muse, mutect2, varscan2
- UNC80 | c.7110A>T p.L2370F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- UNC80 | c.7111G>A p.E2371K | Missense Mutation (SNP) | VAF 6/99 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- USH2A | c.5669G>T p.G1890V | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WDR62 | c.1382A>T p.K461M | Missense Mutation (SNP) | VAF 27/162 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- XIRP2 | c.3035C>T p.P1012L (on ENST00000628543; = p.P1187L on NM_152381.6) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2
- ZBTB45 | c.134G>T p.R45L | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZMYM3 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF182 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- ZNF765 | c.1123A>T p.R375* | Nonsense Mutation (SNP) | VAF 33/448 reads (7%) | called by muse, mutect2
- ZSCAN5B | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 26/347 reads (7%) | called by muse, mutect2
- ANK2 | c.546C>G p.L182= | Silent (SNP) | VAF 42/348 reads (12%) | called by muse, mutect2, varscan2
- ANKRD45 | c.570G>C p.G190= | Silent (SNP) | VAF 16/162 reads (10%) | catalogued as COSV60960021; called by muse, mutect2
- APBA3 | c.1249C>T p.L417= | Silent (SNP) | VAF 5/88 reads (6%) | called by muse, mutect2
- ARMC3 | c.2517G>T p.G839= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as COSV99958892; called by muse, mutect2, varscan2
- CASR | c.2418G>T p.V806= (on ENST00000490131; = p.V883= on NM_000388.4) | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- CDH16 | c.1356C>A p.S452= | Silent (SNP) | VAF 10/108 reads (9%) | called by muse, mutect2
- CDH4 | c.411G>A p.K137= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV100849423; called by muse, mutect2
- COL17A1 | c.2280T>A p.T760= | Silent (SNP) | VAF 35/531 reads (7%) | called by muse, mutect2
- DNAJC6 | c.240G>T p.L80= | Silent (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- ELFN1 | c.2082C>A p.A694= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- EMD | c.672G>T p.P224= | Silent (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- FOXE3 | c.807G>A p.L269= | Silent (SNP) | VAF 4/38 reads (11%) | called by mutect2, varscan2
- GALNT13 | c.1645C>T p.L549= | Silent (SNP) | VAF 22/138 reads (16%) | called by muse, mutect2, varscan2
- GOLGA8M | c.1044G>A p.E348= | Silent (SNP) | VAF 18/464 reads (4%) | called by muse, mutect2
- GOLGA8S | c.1384C>T p.L462= | Silent (SNP) | VAF 46/540 reads (9%) | called by muse, mutect2
- GRIK2 | c.1644A>G p.T548= | Silent (SNP) | VAF 28/388 reads (7%) | catalogued as COSV59758375; called by muse, mutect2
- GRM8 | c.627C>T p.I209= | Silent (SNP) | VAF 64/440 reads (15%) | catalogued as rs562607294, COSV58821992; called by muse, mutect2, varscan2
- IFT27 | c.147G>T p.V49= (on ENST00000433985 / NM_001363003.2; = p.V48= on NM_006860.5) | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- IRS4 | c.2643C>G p.P881= | Silent (SNP) | VAF 34/466 reads (7%) | called by muse, mutect2
- ITIH6 | c.2523G>T p.G841= | Silent (SNP) | VAF 9/102 reads (9%) | called by muse, mutect2
- KIF2B | c.699G>C p.L233= | Silent (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- LAMA4 | c.2916G>T p.L972= (on ENST00000230538 / NM_001105206.3; = p.L965= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/300 reads (10%) | catalogued as COSV57893088; called by muse, mutect2, varscan2
- LILRB5 | c.6C>T p.T2= | Silent (SNP) | VAF 5/143 reads (3%) | called by muse, mutect2
- LNX2 | c.1000C>A p.R334= | Silent (SNP) | VAF 36/363 reads (10%) | called by muse, mutect2, varscan2
- LTBP2 | c.2319C>A p.L773= | Silent (SNP) | VAF 16/195 reads (8%) | called by muse, mutect2
- LTF | c.399C>T p.S133= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as rs1164186938; called by muse, mutect2
- MAGED1 | c.1338T>G p.P446= | Silent (SNP) | VAF 24/197 reads (12%) | called by muse, mutect2, varscan2
- MROH2B | c.2460C>A p.L820= | Silent (SNP) | VAF 47/156 reads (30%) | called by muse, mutect2, varscan2
- NAV1 | c.5532T>C p.D1844= | Silent (SNP) | VAF 21/139 reads (15%) | called by muse, mutect2, varscan2
- NUP35 | c.591G>A p.G197= | Silent (SNP) | VAF 19/204 reads (9%) | catalogued as rs1229890587; called by muse, mutect2, varscan2
- OPRK1 | c.1060C>A p.R354= | Silent (SNP) | VAF 55/211 reads (26%) | catalogued as COSV55570192; called by muse, mutect2, varscan2
- OR10J5 | c.378C>A p.I126= | Silent (SNP) | VAF 6/154 reads (4%) | called by muse, mutect2
- OR56A4 | c.633T>A p.S211= | Silent (SNP) | VAF 39/289 reads (13%) | catalogued as COSV58110517; called by muse, mutect2, varscan2
- PAX5 | c.234C>A p.I78= | Silent (SNP) | VAF 14/185 reads (8%) | called by muse, mutect2
- PCDHA6 | c.1824G>T p.S608= | Silent (SNP) | VAF 10/197 reads (5%) | catalogued as COSV100971175, COSV65343226, COSV65345214; called by muse, mutect2
- PLXNA3 | c.3594G>T p.V1198= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- PLXNB3 | c.4275C>A p.T1425= | Silent (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- PRKCB | c.903G>C p.L301= | Silent (SNP) | VAF 26/256 reads (10%) | called by muse, mutect2
- RCL1 | c.528C>A p.V176= | Silent (SNP) | VAF 26/308 reads (8%) | catalogued as rs532877046, COSV67754611; called by muse, mutect2
- SKAP1 | c.78G>T p.R26= | Silent (SNP) | VAF 22/318 reads (7%) | called by muse, mutect2
- SLC12A3 | c.618C>G p.L206= | Silent (SNP) | VAF 19/225 reads (8%) | called by muse, mutect2
- SLC5A5 | c.1386C>A p.G462= | Silent (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- SLTM | c.828A>T p.A276= | Silent (SNP) | VAF 20/338 reads (6%) | called by muse, mutect2
- ST3GAL3 | c.222G>C p.R74= (on ENST00000361392 / NM_174964.4; = p.R59= on NM_006279.5) | Silent (SNP) | VAF 30/487 reads (6%) | called by muse, mutect2
- SYP | c.849C>T p.G283= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as rs1557102723; called by muse, mutect2, varscan2
- TENM1 | c.5739A>T p.S1913= | Silent (SNP) | VAF 15/119 reads (13%) | called by muse, mutect2, varscan2
- THSD7A | c.4122G>A p.G1374= | Silent (SNP) | VAF 20/180 reads (11%) | called by muse, mutect2, varscan2
- TMEM131L | c.183G>C p.L61= | Silent (SNP) | VAF 12/196 reads (6%) | called by muse, mutect2
- XIRP2 | c.3036T>G p.P1012= (on ENST00000628543; = p.P1187= on NM_152381.6) | Silent (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- ZFC3H1 | c.2298A>T p.T766= | Silent (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- ZFP82 | c.816T>C p.H272= | Silent (SNP) | VAF 20/172 reads (12%) | called by muse, varscan2
- ZNF845 | c.1818G>T p.S606= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as rs776661745; called by muse, mutect2, varscan2
- ZSCAN5B | c.70C>A p.R24= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as rs761690422, COSV62839164; called by muse, mutect2, varscan2
- AC133561.1 | n.1539C>G | RNA (SNP) | VAF 3/28 reads (11%) | called by mutect2, varscan2
- AP001893.2 | chr11:126175756 C>A | 3'Flank (SNP) | VAF 36/264 reads (14%) | called by muse, mutect2, varscan2
- ATG4B | chr2:241637541 C>A | 5'Flank (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- B4GALNT1 | c.712+23C>A | Intron (SNP) | VAF 41/365 reads (11%) | called by muse, mutect2, varscan2
- C11orf49 | chr11:47164102 G>A | 3'Flank (SNP) | VAF 10/50 reads (20%) | catalogued as rs748993342; called by muse, mutect2
- CHRND | c.*680C>G | 3'UTR (SNP) | VAF 27/374 reads (7%) | called by muse, mutect2
- CRACDL | c.-11+38542G>T | Intron (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- CRHR2 | c.184+289G>T | Intron (SNP) | VAF 18/116 reads (16%) | called by muse, mutect2
- DIP2C | c.85+27463A>G | Intron (SNP) | VAF 16/233 reads (7%) | called by muse, mutect2
- FSHR | c.-11G>T | 5'UTR (SNP) | VAF 26/325 reads (8%) | called by muse, mutect2
- FTSJ1 | c.958-35C>A | Intron (SNP) | VAF 22/274 reads (8%) | called by muse, mutect2
- GLTPP1 | n.19C>A | RNA (SNP) | VAF 39/300 reads (13%) | called by muse, mutect2, varscan2
- IGLL3P | n.26C>T | RNA (SNP) | VAF 13/153 reads (8%) | called by muse, mutect2
- IST1 | c.480+47T>G | Intron (SNP) | VAF 7/163 reads (4%) | called by muse, mutect2
- ITSN1 | c.2728-760T>C | Intron (SNP) | VAF 8/219 reads (4%) | called by muse, mutect2
- MASP1 | c.1303+5231C>G | Intron (SNP) | VAF 33/322 reads (10%) | called by muse, mutect2
- MFSD2A | c.*6G>T | 3'UTR (SNP) | VAF 15/135 reads (11%) | catalogued as COSV65686572; called by muse, mutect2, varscan2
- MS4A2 | c.-22G>A | 5'UTR (SNP) | VAF 24/248 reads (10%) | catalogued as rs756548473; called by muse, mutect2
- MYH11 | c.*10T>A | 3'UTR (SNP) | VAF 40/366 reads (11%) | called by muse, mutect2, varscan2
- NDUFAF2 | c.127+44G>A | Intron (SNP) | VAF 16/166 reads (10%) | catalogued as rs754677895; called by muse, mutect2
- NIPAL4 | c.223+164G>C | Intron (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- NTRK3 | c.2133+24G>A | Intron (SNP) | VAF 16/234 reads (7%) | called by muse, mutect2
- OAS3 | c.*16C>T | 3'UTR (SNP) | VAF 20/216 reads (9%) | catalogued as rs748927297; called by mutect2, varscan2
- POLA1 | c.2947-21072C>A | Intron (SNP) | VAF 30/378 reads (8%) | called by muse, mutect2
- PRRT1 | c.20-129C>A | Intron (SNP) | VAF 30/361 reads (8%) | called by muse, mutect2
- RFPL4AP1 | n.423C>T | RNA (SNP) | VAF 49/409 reads (12%) | catalogued as rs895367628; called by muse, mutect2, varscan2
- SNORD116-16 | n.11T>A | RNA (SNP) | VAF 25/257 reads (10%) | called by muse, mutect2, varscan2
- SPATA31D5P | n.1089C>A | RNA (SNP) | VAF 21/332 reads (6%) | called by muse, mutect2
- SPG7 | c.1643-12del | Intron (DEL) | VAF 26/216 reads (12%) | called by mutect2, pindel, varscan2
- TMIGD3 | c.215-613G>A | Intron (SNP) | VAF 4/33 reads (12%) | catalogued as rs1057412678; called by muse, varscan2
- TNMD | c.-17C>T | 5'UTR (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- TRIM48 | c.-40G>C | 5'UTR (SNP) | VAF 24/289 reads (8%) | called by muse, mutect2
- UBE2DNL | n.132G>T | RNA (SNP) | VAF 7/99 reads (7%) | called by muse, mutect2
- ZBTB44-DT | n.399G>T | RNA (SNP) | VAF 50/427 reads (12%) | catalogued as rs1476269901; called by muse, mutect2, varscan2
